Gene-level copy-number profile of tumor specimen TCGA-13-0724-01A from TCGA case TCGA-13-0724, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.1 years (26,342 days).
Specimen TCGA-13-0724-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f609b580-4ab3-4dc5-9636-f5562f2324e5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0724-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c24444be-b4a7-42e1-b811-4d1c4210a036

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 14; copy number 2: 1,121; copy number 3: 563; copy number 4: 30,460; copy number 5: 810; copy number 6: 15,518; copy number 7: 4,215; copy number 8: 3,812; copy number 9: 945; copy number 10: 1,352; copy number 11: 162; copy number 12: 14; copy number 13: 384; copy number 14: 54; copy number 15: 137; copy number 16: 44; copy number 17: 82; copy number 18: 34; copy number 19: 5; copy number 21: 65; copy number 26: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-13-0724-01): tumor purity 0.85, ploidy 2.68, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,275 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–152,709,491, 381 genes, copy number 13 (broad region; genes not listed).
- chr1:155,845,367–156,192,203, 22 genes, copy number 15: AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1.
- chr1:201,464,278–202,319,781, 34 genes, copy number 9 (within-gene range 7–9): PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231, IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A, PTPN7, PTPRVP, LGR6.
- chr1:226,989,865–227,677,443, 20 genes, copy number 9 (within-gene range 7–9): CDC42BPA, AL353689.2, AL353689.3, AL451047.1, AL627308.1, AL627308.2, AL627308.3, LINC01641, NUCKS1P1, AL606462.1, BTF3P9, AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4, RNA5SP77, ZNF678, FAM133FP.
- chr2:45,164,816–46,187,990, 8 genes, copy number 10 (within-gene range 7–10): LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1.
- chr2:98,997,261–100,322,501, 18 genes, copy number 11 (within-gene range 6–11): TSGA10, SMC3P1, AC079447.1, C2orf15, LIPT1, AC092587.1, MITD1, MRPL30, LYG2, LYG1, TXNDC9, EIF5B, REV1, AC018690.1, AFF3, AC092667.1, LINC01104, LONRF2.
- chr3:50,116,022–50,259,362, 8 genes, copy number 12 (within-gene range 6–12): SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1.
- chr3:71,541,970–72,740,525, 27 genes, copy number 10: MIR1284, AC097634.2, FOXP1-IT1, AC097634.3, AC097634.1, EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1, AC134508.2, AC134508.1, RYBP, AC104435.2, RNU1-62P, AC104435.1, RNA5SP136, AC097369.4.
- chr3:72,772,539–72,773,471, 1 gene, copy number 10: AC134050.1.
- chr3:78,161,698–81,368,191, 20 genes, copy number 9–13: RN7SKP61, AC108752.1, MRPS17P3, ROBO1, AC055731.1, RN7SL751P, AC117461.1, MIR3923, HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1.
- chr3:81,509,476–81,509,664, 1 gene, copy number 12: RNU2-28P.
- chr3:93,843,764–99,216,266, 78 genes, copy number 10 (broad region; genes not listed).
- chr3:136,721,394–198,222,513, 1,076 genes, copy number 9–14 (broad region; genes not listed).
- chr6:88,609,897–89,352,722, 16 genes, copy number 10 (within-gene range 8–10): RNGTT, SNORA73, AL079342.3, AL079342.1, AL079342.2, RNU2-61P, AL353135.1, PNRC1, RN7SL336P, SRSF12, AL353135.2, PM20D2, GABRR1, GABRR2, TUBB3P1, UBE2J1.
- chr8:92,699,742–92,879,502, 1 gene, copy number 26 (within-gene range 6–26): FLJ46284.
- chr8:92,765,651–95,811,254, 69 genes, copy number 10–26 (within-gene range 6–26) (broad region; genes not listed).
- chr8:102,125,432–104,256,094, 52 genes, copy number 11–14 (within-gene range 6–14): MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, AP002851.1, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1, FZD6, AC025370.2, CTHRC1, AC012213.3, RNU6-1011P, SLC25A32, AC012213.5, DCAF13, AC012213.2, AC012213.4, AC012213.1, RIMS2, PTMAP15, AC007751.1, AC090686.1.
- chr8:104,590,733–105,804,539, 1 gene, copy number 9 (within-gene range 6–9): ZFPM2.
- chr8:105,142,860–109,345,954, 42 genes, copy number 9: AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2.
- chr8:112,538,889–113,616,958, 6 genes, copy number 15: RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1.
- chr8:115,950,511–119,245,673, 30 genes, copy number 10 (within-gene range 6–10): LINC00536, RNA5SP276, AC090994.1, AC105177.1, EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2.
- chr8:124,488,485–125,367,120, 18 genes, copy number 14 (within-gene range 6–14): TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2.
- chr8:125,648,327–131,712,980, 77 genes, copy number 18–21 (broad region; genes not listed).
- chr8:132,507,962–132,848,807, 7 genes, copy number 16: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1.
- chr11:38,498,995–39,874,388, 7 genes, copy number 9: AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1.
- chr11:45,885,651–46,739,506, 27 genes, copy number 9: MAPK8IP1, AC068385.1, C11orf94, PEX16, LARGE2, PHF21A, AC024475.1, AC024475.3, AC024475.2, LINC02710, AC116021.1, LINC02489, CREB3L1, DGKZ, MIR4688, MDK, CHRM4, AMBRA1, AC024293.1, MIR3160-1, MIR3160-2, AC127035.1, HARBI1, ATG13, ARHGAP1, ZNF408, F2.
- chr11:46,753,125–46,758,873, 2 genes, copy number 9: MIR5582, AC115088.1.
- chr11:55,572,128–57,701,182, 134 genes, copy number 9–11 (broad region; genes not listed).
- chr12:31,280,422–31,811,190, 27 genes, copy number 10: AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2.
- chr14:18,333,726–21,116,703, 170 genes, copy number 10–16 (broad region; genes not listed).
- chr16:5,010,909–5,235,822, 11 genes, copy number 11: NAGPA-AS1, NAGPA, ALG1, C16orf89, AC026458.1, EEF2KMT, AC026458.2, AC074051.3, ENPP7P14, AC074051.1, LINC02164.
- chr16:5,260,686–5,366,688, 4 genes, copy number 11: AC074051.2, RPS3AP48, SNRPCP20, NPM1P3.
- chr17:49,132,460–49,583,827, 23 genes, copy number 9: B4GALNT2, AC069454.1, GNGT2, ABI3, PHOSPHO1, FLJ40194, MIR6129, ZNF652, AC091180.2, AC091180.5, AC091180.4, AC091180.1, PHB, AC091180.3, Y_RNA, EIF4EP2, LINC02075, AC015656.1, NGFR, AC006487.1, MIR6165, AC006487.2, NXPH3.
- chr19:11,987,617–18,000,080, 350 genes, copy number 10–19 (within-gene range 4–19) (broad region; genes not listed).
- chr19:23,204,010–32,072,113, 121 genes, copy number 10–17 (within-gene range 6–17) (broad region; genes not listed).
- chr19:34,758,073–36,498,159, 127 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr19:36,850,361–40,021,038, 155 genes, copy number 9 (broad region; genes not listed).
- chr20:17,613,678–20,738,731, 68 genes, copy number 10 (broad region; genes not listed).
- chr20:50,510,321–51,010,019, 18 genes, copy number 10: PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1.
- chr22:29,705,256–30,177,075, 17 genes, copy number 9 (within-gene range 4–9): AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
